Somatic mutation profile of tumor specimen ALCH-ACHI-TTP1-A (aliquot ALCH-ACHI-TTP1-A-1-0-D-A501-36) from ALCHEMIST case ALCH-ACHI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.7 years (23,619 days).
Specimen ALCH-ACHI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f088d74d-90ca-45d9-9f5e-74b0e21f878c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ACHI-NB1-A (Blood Derived Normal), aliquot ALCH-ACHI-NB1-A-1-0-D-A501-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d06d5218-06c7-4a7e-98be-bba4cadf0bca

The open-access MAF lists 87 somatic variants for this specimen: 56 protein-altering or splice-affecting, 14 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 14, Intron 7, Nonsense Mutation 4, 3'UTR 4, 5'Flank 3, Splice Site 1, Splice Region 1, 3'Flank 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 48/482 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACMSD | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as rs757421443, COSV51607251; called by muse, varscan2
- CARD11 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs755090332; called by muse, mutect2
- CD58 | c.708T>C p.G236= | Splice Region (SNP) | VAF 21/310 reads (7%) | catalogued as rs1460465790; called by muse, mutect2
- CFH | c.3200A>G p.Y1067C | Missense Mutation (SNP) | VAF 48/702 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776101291; called by muse, mutect2
- DSC1 | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 38/524 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57152250; called by muse, mutect2
- EP300 | c.3766C>T p.Q1256* | Nonsense Mutation (SNP) | VAF 37/886 reads (4%) | catalogued as COSV54335815; called by muse, mutect2
- FTCD | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as rs368782658; called by muse, mutect2
- HMCN1 | c.7328G>T p.R2443L | Missense Mutation (SNP) | VAF 30/295 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV54921083; called by muse, mutect2
- HNF1B | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); catalogued as rs1568675935; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KMT2A | c.11807G>A p.R3936Q | Missense Mutation (SNP) | VAF 34/676 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.835); catalogued as rs1308143825; called by muse, mutect2
- LBHD1 | c.655G>C p.E219Q (on ENST00000431002 / NM_001367940.1; = p.E193Q on NM_024099.3) | Missense Mutation (SNP) | VAF 17/268 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.762); catalogued as rs1316322619; called by muse, mutect2
- MAPKAPK2 | c.997C>G p.Q333E | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1363748424; called by muse, mutect2
- MED23 | c.479T>G p.L160R | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs786205583; called by muse, mutect2, varscan2
- MTNR1B | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 11/276 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as rs1301989909, COSV99925288; called by muse, mutect2
- MYH11 | c.5767G>A p.A1923T | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs571504063, COSV55542134; ClinVar: uncertain significance; called by muse, mutect2
- OR13G1 | c.579G>C p.E193D | Missense Mutation (SNP) | VAF 40/349 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.09); catalogued as COSV62944036; called by muse, mutect2, varscan2
- RP1L1 | c.2171C>T p.S724L | Missense Mutation (SNP) | VAF 24/455 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs370521287; called by muse, mutect2
- TTN | c.54271C>T p.H18091Y (on ENST00000591111; = p.H10667Y on NM_003319.4) | Missense Mutation (SNP) | VAF 19/396 reads (5%) | PolyPhen benign (0.083); catalogued as COSV60268524; called by muse, mutect2
- VIT | c.1822G>A p.D608N (on ENST00000389975 / NM_001177969.1; = p.D623N on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs751781886; called by muse, varscan2
- ACSF3 | c.1023G>C p.E341D | Missense Mutation (SNP) | VAF 36/565 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.034); called by muse, mutect2
- ADK | c.813G>A p.M271I (on ENST00000286621; = p.M254I on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/478 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- AGRN | c.5149G>C p.E1717Q | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- AP002748.5 | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 30/672 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); called by muse, mutect2
- ARID1A | c.6067G>T p.E2023* | Nonsense Mutation (SNP) | VAF 16/420 reads (4%) | called by muse, mutect2
- ARRDC4 | c.562T>G p.W188G | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- BANP | c.1555C>T p.Q519* (on ENST00000286122; = p.Q469* on NM_017869.4) | Nonsense Mutation (SNP) | VAF 9/183 reads (5%) | called by muse, mutect2
- C4B | c.2539G>C p.E847Q | Missense Mutation (SNP) | VAF 34/738 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDC6 | c.747G>C p.E249D | Missense Mutation (SNP) | VAF 19/301 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); called by muse, mutect2
- CFDP1 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 19/515 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CMYA5 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CTTNBP2 | c.1142T>A p.I381N | Missense Mutation (SNP) | VAF 45/356 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- CUBN | c.8405C>T p.T2802I | Missense Mutation (SNP) | VAF 12/402 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2
- DYNC2H1 | c.11359T>A p.S3787T | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.057); called by muse, mutect2
- EBLN1 | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 48/478 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.282); called by muse, mutect2
- ECPAS | c.3023A>G p.E1008G | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- GPR148 | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KIFC1 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 31/544 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.01); called by muse, mutect2
- KYAT3 | c.185A>C p.D62A | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- MPLKIP | c.406T>A p.L136M | Missense Mutation (SNP) | VAF 42/461 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.017); called by muse, mutect2
- PPP2R3A | c.1879G>C p.E627Q | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2
- PPP3CA | c.1144G>C p.D382H | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- RHBDF1 | c.1998C>G p.I666M | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- RICTOR | c.2148C>G p.I716M | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SAMHD1 | c.1558A>G p.K520E (on ENST00000262878 / NM_001363729.2; = p.K555E on NM_015474.4) | Missense Mutation (SNP) | VAF 117/728 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEMA6A | c.1037A>G p.Q346R | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2
- SLC2A12 | c.554C>G p.S185* | Nonsense Mutation (SNP) | VAF 10/324 reads (3%) | called by muse, mutect2
- SRGAP1 | c.836G>A p.R279K | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.298); called by muse, mutect2
- SRSF11 | c.719-1G>C p.X240_splice | Splice Site (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.977C>A p.P326Q | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- TMEM176B | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 28/618 reads (5%) | SIFT tolerated (0.85); PolyPhen benign (0.056); called by muse, mutect2
- TSPAN33 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBE2O | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2
- USP48 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.05); called by muse, mutect2
- ZNF33B | c.370A>T p.I124L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF507 | c.809A>T p.H270L | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACKR1 | c.495C>T p.L165= | Silent (SNP) | VAF 10/133 reads (8%) | catalogued as COSV63674519; called by muse, mutect2
- BEGAIN | c.534C>A p.V178= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- CDC6 | c.546C>T p.I182= | Silent (SNP) | VAF 30/452 reads (7%) | catalogued as COSV52929786; called by muse, mutect2
- CHST5 | c.672C>T p.R224= | Silent (SNP) | VAF 23/206 reads (11%) | catalogued as rs780592004, COSV60336719; called by muse, mutect2, varscan2
- CLSPN | c.243T>C p.Y81= | Silent (SNP) | VAF 16/185 reads (9%) | catalogued as rs1267067845; called by muse, mutect2
- COPG1 | c.2127G>T p.L709= | Silent (SNP) | VAF 37/212 reads (17%) | called by muse, mutect2, varscan2
- CUL4B | c.2208T>C p.F736= | Silent (SNP) | VAF 18/216 reads (8%) | called by muse, mutect2
- ERBB2 | c.2964C>T p.V988= | Silent (SNP) | VAF 30/374 reads (8%) | called by muse, mutect2
- FN1 | c.2379A>T p.I793= | Silent (SNP) | VAF 92/790 reads (12%) | called by muse, mutect2, varscan2
- GPANK1 | c.174G>A p.Q58= | Silent (SNP) | VAF 23/390 reads (6%) | catalogued as rs1318694279; called by muse, mutect2
- GRM6 | c.2304C>T p.Y768= | Silent (SNP) | VAF 43/290 reads (15%) | catalogued as rs140789330; called by muse, mutect2, varscan2
- HMCN1 | c.7329G>T p.R2443= | Silent (SNP) | VAF 31/296 reads (10%) | called by muse, mutect2
- SH3RF3 | c.2259C>T p.D753= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as rs1322906700; called by muse, mutect2
- SIGIRR | c.150G>A p.L50= | Silent (SNP) | VAF 31/495 reads (6%) | catalogued as COSV58986525; called by muse, mutect2
- AC133561.1 | n.1907C>A | RNA (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504883 C>A | 5'Flank (SNP) | VAF 25/200 reads (13%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504884 C>T | 5'Flank (SNP) | VAF 25/199 reads (13%) | catalogued as rs990168006; called by muse, mutect2, varscan2
- AREG | c.*83G>T | 3'UTR (SNP) | VAF 16/404 reads (4%) | called by muse, mutect2
- CACNG4 | c.*799C>T | 3'UTR (SNP) | VAF 60/429 reads (14%) | catalogued as rs1481459676; called by muse, mutect2, varscan2
- CCDC107 | chr9:35657945 C>A | 5'Flank (SNP) | VAF 22/171 reads (13%) | called by muse, mutect2, varscan2
- EDC4 | c.3629+37G>C | Intron (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- ETHE1 | c.227-37C>T | Intron (SNP) | VAF 9/161 reads (6%) | catalogued as rs1313885342; called by muse, mutect2
- KLC2 | c.1267-15C>T | Intron (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- LEF1 | c.214-1130C>T | Intron (SNP) | VAF 40/330 reads (12%) | called by muse, varscan2
- MFSD4B | c.*656dup | 3'UTR (INS) | VAF 50/337 reads (15%) | catalogued as rs753457365; called by mutect2, pindel, varscan2
- PSMC3IP | c.-22G>A | 5'UTR (SNP) | VAF 24/540 reads (4%) | called by muse, mutect2
- RMDN3 | c.1278+10T>G | Intron (SNP) | VAF 28/291 reads (10%) | called by muse, mutect2
- SELENOS | c.76+110A>C | Intron (SNP) | VAF 16/122 reads (13%) | called by muse, mutect2, varscan2
- TAT | c.1224+19C>T | Intron (SNP) | VAF 17/302 reads (6%) | called by muse, mutect2
- UBE4A | chr11:118401589 G>A | 3'Flank (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- UQCRB | c.*3582T>C | 3'UTR (SNP) | VAF 76/597 reads (13%) | called by muse, mutect2, varscan2
